Surgical pathology report (de-identified scan), TCGA case TCGA-EY-A2ON, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of North Carolina, specimen TCGA-EY-A2ON-01A (Primary Tumor).

[page 1 of 5]
PATHOLOGY REVISED REPORT

100-0-3

Carcinoma, serous, NOS

Site: Endometrium 8441/3
C54.1

fw
8/24/11

Diagnosis:

A: Omentum, resection

- Involved by serous carcinoma, largest focus 11.5 cm in greatest dimension

B: Uterus, tubes and ovaries, hysterectomy with bilateral salpingo-oophorectomy

Uterus and cervix, hysterectomy:

Location of tumor: anterior and posterior endometrium

Histologic type: high grade uterine papillary serous carcinoma with associated calcifications

Histologic grade (FIGO): grade 3

Extent of invasion: involves uterus, cervix, and bilateral adnexae

Myometrial invasion: outer half, extends to <1 mm from the serosa in the uterine body and involves the serosa in the posterior lower uterine segment

Lower uterine segment involvement: present

Cervical involvement: present; also, there is a small amount of soft tissue attached to the posterior aspect of the cervix, which is involved by microscopic foci of serous carcinoma

Adnexal involvement (see below): present

Other sites: not applicable

Cervical/vaginal margin and distance: vaginal margin distance 6 mm (small portion of vagina attached to posterior cervix)

Lymphovascular space invasion: present

Regional lymph nodes: not applicable

Other pathologic findings:

- Chronic cervicitis with reactive epithelial changes

[page 2 of 5]
- Multiple leiomyomas measuring up to 3.2 cm in greatest dimension

Tumor estrogen receptor and progesterone receptor immunohistochemistry results:

Estrogen receptor (Ventana, clone SP1): Weakly positive 10%, very weak intensity

Progesterone receptor (Ventana, clone 1E2): Positive 10%, 1 to 2+

AJCC Pathologic Stage: pT3a pNx

FIGO (2008 classification) Stage grouping:

These stages are based on information available at the time of this report, and are subject to change pending additional information and clinical review.

Ovary, right, oophorectomy:

- Involved by serous carcinoma
- Few tumor foci measuring up to 3 mm
- Surface involvement present
- Physiologic changes

Ovary, left, oophorectomy:

- Involved by metastatic serous carcinoma
- Few tumor foci measuring up to 5 mm
- Surface involvement present
- Physiologic changes

Fallopian tube, right, salpingectomy:

- Serous carcinoma involves serosal surface
- Detached fragments of carcinoma in tubal lumen, but no tubal epithelial involvement
- Endosalpingiosis
- Fimbria with vascular congestion and lymphatic dilatation

Fallopian tube, left, salpingectomy:

- Serous carcinoma involves serosal surface
- Detached fragments of carcinoma in tubal lumen, but no tubal epithelial involvement
- Paratubal tissue with benign ectopic adrenal cortex

Comment:

This serous carcinoma is considered to be of endometrial origin since morphology of tumor is the same in endometrium and ovaries, endometrial tumor is large while ovarian is small,

[page 3 of 5]
there is deep myometrial invasion and lymphovascular space invasion, tumor involves bilateral ovaries, several small foci are seen in each ovary, and there is ovarian surface involvement as well as parenchymal involvement.

Immunohistochemical stain for CD31 supports both lymphovascular space invasion and myometrial tumor with artifactual clearing around invasive tumor foci.

Clinical History:

This is a -year-old female with endometrial cancer.

Gross Description:

Specimen A is received in one appropriately labeled container, additionally labeled "omentum" and consist of one aggregate of yellow fatty omentum weighing 310 grams and measuring 15 cm x 16 cm x 7 cm. Sectioning through this omentum reveals at least 3 large tumor nodules measuring 11.5 x 4.0 x 1.5 cm; 6.5 x 3.0 x 1.5 cm; and 5.5 x 2.3 x 1.5 cm. The cut surface of these nodules is yellow and firm. Representative sections of tumor are placed into blocks A1-A5. A representative section of uninvolved omentum is placed into block A6.

Specimen B is received in one appropriately labeled container.

Adnexa: Present bilaterally

Weight: 300 grams

Shape: Pear shaped, with large subserosal irregular nodularities. The largest of these is on the posterior surface and measures 3.2 cm.

Dimensions:

height: 13.5 cm

anterior to posterior width: 5.8 cm

breadth at fundus: 7.0 cm

Serosa: Tan, smooth, nodule with 2-3 pedunculated white whorled firm lesion (greatest dimension 2.3 cm)

Cervix:

length of endocervical canal: 4.5 cm

ectocervix: Tan, hemorrhagic

endocervix: Tan, rough, hemorrhagic

Endomyometrium:

length of endometrial cavity: 5.0 cm

width of endometrial cavity at fundus: 4.7 cm

tumor findings:

dimensions: 4.5 x 3.8 x 1.5 cm

[page 4 of 5]
appearance: Fungating, irregular, tan/brown, friable
location and extent: Gross involvement by both the anterior and posterior endometrium.

myometrial invasion: Inner one-half
thickness of myometrial wall at deepest gross invasion: 2.5 cm
other findings or comments: There are numerous (6-8) white whorled nodules found in the myometrium. The largest of these measures 2.4 cm x 2.5 cm x 3.2 cm.

Adnexa:

Right ovary:

dimensions: 4.0 cm x 1.1 cm x 1.7 cm

external surface: White, bosselated

cut surface: White/tan/yellow with one clear fluid filled cyst measuring 0.6 cm without excrescences.

Right fallopian tube:

dimensions: 7.5 cm x 0.9 cm

other findings: This fallopian tube has been fragmented into two pieces proximally. The lumen of the right fallopian tube is white and firm.

Left ovary:

dimensions: 4.7 cm x 0.8 cm x 1.4 cm

external surface: White, bosselated

cut surface: White/tan

Left fallopian tube:

dimensions: 6.5 cm x 0.8 cm

other findings: None

Lymph nodes: None identified

Other comments: None

Digital photograph taken: Not taken

Tissue submitted for special investigations: Tumor

Block Summary:

B1 - anterior cervix

B2 - anterior lower uterine segment

B3-B4 - anterior mid corpus, bisected

B5-B6 - anterior upper corpus, bisected

B7 - posterior cervix

B8-B9 - posterior lower uterine segment

B10-B12 - posterior mid corpus

B13-B14 - posterior upper corpus, bisected

B15 - right ovary

B16-B17 - right fallopian tube

[page 5 of 5]
B18 - left ovary

B19-B20 - left fallopian tube

B21-B24 - white whorled nodules in myometrium

Source: NCI Genomic Data Commons file e93c5083-f1e8-4b06-8a52-1e260b11a965 (TCGA-EY-A2ON.AB1B272C-E1ED-4E7B-AAD2-F6B7E741E134.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).